Surgical pathology report (de-identified scan), TCGA case TCGA-CC-A8HS, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-A8HS-01A (Primary Tumor).

[page 1 of 5]
Clinical Case Report (For Collection of Cancerous Tissue)

ICD-O-3
Carcinoma, Hepatocellular NOS
817013

Site: Liver C22.0

QD 11/26/13

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the _____ with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight		VIETNAMESE	
☒ Male ☐ Female			Blood Pressure	Heart Rate
			13/8	

HISTORY OF PRESENT ILLNESS

Chief Complaints: Abdominal pain, bloating, fever

Symptoms: Tired of eating; weight loss.

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic
☐ 80-90 Symptomatic but Fully Ambulatory
☐ 60-70 Symptomatic, in bed less than 50% of day
☒ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden
☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses		# of Pregnancies
	Date of Last Menses		# of Live Births
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____			Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☒ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers: _____						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT x	A tumor was found in the liver	
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Liver Cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging	Date of Diagnosis	
T3 N1 M0 Stage: III C		

Treatment Information

SURGICAL TREATMENT		
Procedure		Date of Procedure
Resection of the right liver		
Primary Tumor		
Organ	Detailed Location	Size
Liver Tumor	Right liver	6 x 5 x 5 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T3 N1 M0 Stage: III C		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
min		min		min			

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Liver Tumor	6 x 5 x 5 cm	Right Liver	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3 N 1 M 0		Stage: III C	
Notes: lymph nodes 5 (positive 5, negative 0)			

[page 5 of 5]
Consolidated Pathology Diagnosis

Cellular Distribution									
Cell Distribution		+	-	Structural Pattern		+	-		
Diffuse				Streaming					
Mosaic				Storiform					
Necrosis				Fibrosis					
Lymphocytic Infiltration				Palisading					
Vascular Invasion				Cystic Degeneration					
Clusterized				Bleeding					
Alveolar Formation				Myxoid Change					
Indian File				Psammoma/Calcification					

Cellular Differentiation															
Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-	Lymphomatous		+	-
Squamoid Cell				Glandular cell				Round Cell				Large Cell			
Spindle Cell				Cell Stratification				Fibroblast				Small Cell			
Keratin				Secretion				Osteoblast				RS Cell/RS Like			
Desmosome				Intracyt. Vacuole				Lipoblast				Inflam. Cell			
Pearl				Gland formation				Myoblast				Plasma Cell			

Cellular Differentiation: ☐ Well ☐ Moderate ☐ Poor

Nuclear Atypia				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis				
Hyperchromatism				
Nucleolar Prominent				
Multinucleated Giant Cell				
Mitotic Activity				

Nuclear Grade: 1

Final Pathology Report

Histological Diagnosis: Hepatocellular Carcinoma **Grade:** 1

Comments: D1 90%, D2 90%, D3 90%, D4 90%,
M1 - M2 - Carcinoma metastasizes to LN

Date

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGISTS

Diagnosis Uncontested	✓	
Primary Tumor Site Uncontested	✓	
Metastatic Site Uncontested	✓	
Reviewed Initials: KIM Date Reviewed: 11/8/13		

Source: NCI Genomic Data Commons file 956fc257-5e21-4df2-a121-34b51a3b4bbd (TCGA-CC-A8HS.D7967904-FE4B-4BB5-92B2-5354404AC939.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).